Gene-level copy-number profile of tumor specimen TCGA-VR-A8EW-01A from TCGA case TCGA-VR-A8EW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 57.2 years (20,902 days).
Specimen TCGA-VR-A8EW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.395d4a42-8be8-4a35-9eb9-26b065b0bf6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8EW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f980c4a4-76e0-4e6a-b990-30fa3ba004b1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 99; copy number 2: 10,159; copy number 3: 26,669; copy number 4: 16,366; copy number 5: 3,973; copy number 6: 1,217; copy number 7: 700; copy number 8: 529; copy number 12: 4; copy number 13: 3; copy number 15: 25; copy number 24: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8EW-01A-11D-A36I-01): tumor purity 0.53, ploidy 6.1, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,324 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:128,872,349–198,222,513, 1,226 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr4:170,742,469–170,891,597, 3 genes, copy number 8: LINC02382, AC097486.1, RNU6ATAC13P.
- chr11:68,707,440–71,818,238, 88 genes, copy number 15–24 (within-gene range 2–24) (broad region; genes not listed).
- chr17:53,276,760–54,365,634, 1 gene, copy number 12 (within-gene range 3–13): AC034268.2.
- chr17:53,434,131–53,955,324, 6 genes, copy number 12–13: AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
